Somatic mutation profile of tumor specimen C3L-05973-02 (aliquot CPT0346560006) from CPTAC case C3L-05973, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.5 years (25,391 days).
Specimen C3L-05973-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6b5433c-97af-4695-8a9c-95b0c8460809.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05973-31 (Blood Derived Normal), aliquot CPT0346650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95b1a1c8-9293-45d3-aec8-5d1c5bba6665

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Intron 2, Nonsense Mutation 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 57/470 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KIT | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 30/292 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913512, CM002803, COSV55387507, COSV55411978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 29/565 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV67241917; called by muse, mutect2
- ANPEP | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs373183009; called by muse, mutect2, varscan2
- APOBEC3A | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 61/600 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs746848561; called by muse, varscan2
- CFH | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs932614951; called by muse, mutect2, varscan2
- EXOC2 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 28/338 reads (8%) | catalogued as COSV57863822; called by muse, mutect2
- FBXL3 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762998083; called by muse, mutect2, varscan2
- FSTL5 | c.626T>G p.L209R | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100055479, COSV60187156, COSV60193080; called by muse, mutect2, varscan2
- HTATIP2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778154551, COSV58175963; called by muse, mutect2
- MTCL1 | c.5104C>T p.R1702C (on ENST00000306329 / NM_001378206.1; = p.R1383C on NM_015210.4) | Missense Mutation (SNP) | VAF 50/558 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748228384, COSV60404388; called by muse, mutect2
- OR10J1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.082); catalogued as rs760810730; called by muse, mutect2, varscan2
- POLE | c.347T>C p.V116A | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs771744496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF34 | c.541T>C p.S181P | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.422); catalogued as COSV63442012; called by muse, mutect2
- SBK3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs1268193491; called by muse, mutect2
- SLC15A2 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 55/299 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs758759841, COSV55197813; called by muse, mutect2, varscan2
- SLC6A9 | c.130T>C p.F44L | Missense Mutation (SNP) | VAF 35/356 reads (10%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as COSV100745975; called by muse, mutect2
- TAS1R1 | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 45/465 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781280561; called by muse, mutect2
- TGFBR1 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs200657153, COSV66626839; called by muse, mutect2, varscan2
- TTC26 | c.1646A>G p.E549G | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs774071855; called by muse, mutect2, varscan2
- ADGRG4 | c.5747C>A p.P1916H | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- BRINP2 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 38/361 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCHS1 | c.7927T>C p.S2643P | Missense Mutation (SNP) | VAF 51/510 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DPP6 | c.1436C>T p.S479F (on ENST00000377770 / NM_001364500.2; = p.S417F on NM_001936.5) | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.943); called by muse, mutect2
- EMX1 | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 54/564 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- HDAC8 | c.1103A>T p.Y368F | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- HTR1A | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 27/522 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2
- LRRFIP1 | c.592A>T p.M198L (on ENST00000392000 / NM_001137552.2; = p.M174L on NM_004735.4) | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- MAN1B1 | c.1257G>A p.E419= | Splice Region (SNP) | VAF 14/279 reads (5%) | called by muse, mutect2
- MYRFL | c.1483C>A p.H495N | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- NIPBL | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 44/343 reads (13%) | called by muse, mutect2, varscan2
- PRKD3 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- RHOH | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 41/540 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.242); called by muse, mutect2
- RPGR | c.1434G>A p.M478I | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SERTAD1 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 75/482 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SEZ6L2 | c.147G>C p.E49D | Missense Mutation (SNP) | VAF 11/385 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2
- SMARCD3 | c.425A>G p.D142G (on ENST00000262188 / NM_001003801.2; = p.D129G on NM_003078.4) | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- WNT6 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 52/626 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); called by muse, mutect2
- ZEB2 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 34/422 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2
- ZHX3 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 19/502 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- ZNF354A | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 25/398 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZSCAN20 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALOX5 | c.822G>A p.E274= | Silent (SNP) | VAF 42/401 reads (10%) | catalogued as COSV65553391; called by muse, mutect2, varscan2
- ALOX5AP | c.447G>A p.T149= | Silent (SNP) | VAF 30/337 reads (9%) | catalogued as rs199751347; called by muse, mutect2
- DCHS1 | c.3792C>T p.F1264= | Silent (SNP) | VAF 29/220 reads (13%) | called by muse, mutect2, varscan2
- DSCAML1 | c.393G>A p.P131= (on ENST00000321322; = p.P71= on NM_020693.4) | Silent (SNP) | VAF 46/506 reads (9%) | catalogued as rs564744017, COSV58382263, COSV58387021; called by muse, mutect2
- KCNC3 | c.798C>T p.G266= | Silent (SNP) | VAF 55/421 reads (13%) | called by muse, mutect2, varscan2
- MYH15 | c.4180A>C p.R1394= | Silent (SNP) | VAF 30/270 reads (11%) | called by muse, mutect2, varscan2
- NEO1 | c.1716T>C p.Y572= | Silent (SNP) | VAF 31/354 reads (9%) | called by muse, mutect2
- NIBAN2 | c.246C>T p.S82= | Silent (SNP) | VAF 34/315 reads (11%) | called by muse, mutect2, varscan2
- OR8B8 | c.433T>C p.L145= | Silent (SNP) | VAF 49/535 reads (9%) | called by muse, mutect2
- PIWIL3 | c.474C>T p.L158= | Silent (SNP) | VAF 24/367 reads (7%) | catalogued as COSV59995835; called by muse, mutect2
- RCE1 | c.72G>A p.A24= | Silent (SNP) | VAF 51/423 reads (12%) | catalogued as rs369200658; called by muse, mutect2, varscan2
- TG | c.243G>T p.L81= | Silent (SNP) | VAF 33/495 reads (7%) | called by muse, mutect2
- TGFB1 | c.957C>T p.A319= | Silent (SNP) | VAF 53/529 reads (10%) | called by muse, mutect2, varscan2
- UNC5D | c.1998T>C p.C666= | Silent (SNP) | VAF 42/494 reads (9%) | called by muse, mutect2
- VSIG10L2 | c.1128C>T p.N376= | Silent (SNP) | VAF 44/414 reads (11%) | catalogued as rs1230448203; called by muse, mutect2, varscan2
- ZNF727 | c.175A>C p.R59= | Silent (SNP) | VAF 26/249 reads (10%) | catalogued as COSV71647188; called by muse, mutect2, varscan2
- ARHGDIA | c.*339A>G | 3'UTR (SNP) | VAF 59/507 reads (12%) | catalogued as rs964875144; called by muse, mutect2, varscan2
- CRHR2 | c.1095+245G>T | Intron (SNP) | VAF 41/452 reads (9%) | called by muse, mutect2
- SUSD4 | c.725-5703C>A | Intron (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
